Somatic mutation profile of tumor specimen C3N-02158-04 (aliquot CPT0118880006) from CPTAC case C3N-02158, project CPTAC-3 (Bronchus and lung — Adenomas and Adenocarcinomas). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IIIA; Tumor grade: G2; Age at diagnosis: 54.4 years (19,855 days).
Specimen C3N-02158-04: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) fab7a8d0-3008-4869-b186-bcd1f8d0ad62.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-02158-31 (Blood Derived Normal), aliquot CPT0120110002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4075f840-e295-42a9-895a-62f837d6e0cc

The open-access MAF lists 50 somatic variants for this specimen: 40 protein-altering or splice-affecting, 5 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 33, Silent 5, Frame Shift Del 3, Nonsense Mutation 3, Intron 2, RNA 2, In Frame Del 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EGFR | c.2235_2249del p.E746_A750del | In Frame Del (DEL) | VAF 118/380 reads (31%) | hotspot (GDC flag); catalogued as rs121913421, COSV51765119; ClinVar: drug response; called by mutect2, pindel*, varscan2
- SMARCA4 | c.3404G>A p.R1135Q | Missense Mutation (SNP) | VAF 38/284 reads (13%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100758997, COSV60787834; called by muse, mutect2, varscan2
- ANKRD33B | c.752G>T p.C251F | Missense Mutation (SNP) | VAF 74/269 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.658); catalogued as COSV56980503; called by muse, mutect2, varscan2
- CD33 | c.595A>T p.I199F | Missense Mutation (SNP) | VAF 24/182 reads (13%) | SIFT tolerated (0.06); PolyPhen benign (0.012); catalogued as COSV51800218; called by muse, mutect2, varscan2
- COL20A1 | c.922G>A p.V308M | Missense Mutation (SNP) | VAF 17/155 reads (11%) | SIFT tolerated (0.09); PolyPhen benign (0.125); catalogued as rs774028550, COSV58926585; called by muse, mutect2, varscan2
- CUL3 | c.923del p.N308Mfs*3 | Frame Shift Del (DEL) | VAF 35/175 reads (20%) | catalogued as COSV52368769; called by mutect2, pindel, varscan2
- DIDO1 | c.6317A>G p.Q2106R | Missense Mutation (SNP) | VAF 182/703 reads (26%) | SIFT deleterious (0.03); PolyPhen benign (0.005); catalogued as rs773333280, COSV56623502; called by muse, mutect2, varscan2
- DOCK6 | c.1408G>A p.E470K | Missense Mutation (SNP) | VAF 24/145 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs970528614; called by muse, mutect2, varscan2
- EIF2A | c.1181G>T p.G394V | Missense Mutation (SNP) | VAF 29/171 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56408633; called by muse, mutect2, varscan2
- F9 | c.934T>C p.Y312H | Missense Mutation (SNP) | VAF 30/126 reads (24%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.493); catalogued as CM1313145; called by muse, mutect2, varscan2
- FASN | c.1969C>T p.P657S | Missense Mutation (SNP) | VAF 39/331 reads (12%) | SIFT tolerated (0.6); PolyPhen benign (0); catalogued as COSV100148187; called by muse, mutect2, varscan2
- FSIP2 | c.14306A>C p.Q4769P | Missense Mutation (SNP) | VAF 11/98 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.302); catalogued as rs1483726840; called by muse, mutect2, varscan2
- KAZN | c.1954G>A p.E652K | Missense Mutation (SNP) | VAF 56/266 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.734); catalogued as rs1271683187, COSV65726726; called by muse, mutect2, varscan2
- LRRC14B | c.1195C>T p.P399S | Missense Mutation (SNP) | VAF 34/240 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1337337855; called by muse, mutect2, varscan2
- MAP2K5 | c.82G>A p.A28T | Missense Mutation (SNP) | VAF 31/222 reads (14%) | SIFT tolerated (0.24); PolyPhen benign (0.18); catalogued as COSV99459288; called by muse, mutect2, varscan2
- PLAA | c.1426C>T p.R476W | Missense Mutation (SNP) | VAF 25/197 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs754016270, COSV101263518; called by muse, mutect2, varscan2
- SLC9A6 | c.1202T>A p.L401Q | Missense Mutation (SNP) | VAF 16/322 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV65788583; called by muse, mutect2
- TSPAN1 | c.449G>A p.C150Y | Missense Mutation (SNP) | VAF 25/221 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1195740157; called by muse, mutect2, varscan2
- CACNB2 | c.220G>T p.A74S (on ENST00000324631 / NM_201596.3; = p.A19S on NM_000724.4) | Missense Mutation (SNP) | VAF 58/348 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CHST7 | c.1282C>T p.R428W | Missense Mutation (SNP) | VAF 18/136 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- CSE1L | c.1702G>T p.E568* | Nonsense Mutation (SNP) | VAF 77/218 reads (35%) | called by muse, mutect2, varscan2
- DNAH5 | c.12410A>G p.Q4137R | Missense Mutation (SNP) | VAF 66/547 reads (12%) | SIFT tolerated (0.34); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- EDA | c.925G>A p.V309I | Missense Mutation (SNP) | VAF 37/356 reads (10%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.765); called by muse, mutect2, varscan2
- FERMT3 | c.1525C>T p.P509S (on ENST00000279227 / NM_178443.3; = p.P505S on NM_031471.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 37/332 reads (11%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- GAREM2 | c.974C>T p.A325V | Missense Mutation (SNP) | VAF 13/139 reads (9%) | SIFT tolerated (0.52); PolyPhen benign (0.053); called by muse, mutect2, varscan2
- IL11 | c.275G>T p.G92V | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.657); called by mutect2, varscan2
- KCNC4 | c.923A>T p.D308V | Missense Mutation (SNP) | VAF 32/223 reads (14%) | SIFT tolerated (0.28); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- KCNS1 | c.834C>G p.F278L | Missense Mutation (SNP) | VAF 24/229 reads (10%) | SIFT tolerated (0.17); PolyPhen benign (0.086); called by muse, mutect2, varscan2
- KDM5C | c.2969G>T p.C990F | Missense Mutation (SNP) | VAF 17/165 reads (10%) | SIFT tolerated (0.08); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- KDM6B | c.2426C>T p.S809F | Missense Mutation (SNP) | VAF 34/242 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.058); called by muse, mutect2, varscan2
- KDR | c.1162G>C p.V388L | Missense Mutation (SNP) | VAF 38/360 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.243); called by muse, mutect2, varscan2
- LRRTM1 | c.1243G>C p.G415R | Missense Mutation (SNP) | VAF 23/156 reads (15%) | SIFT tolerated (0.5); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- MROH1 | c.1834C>T p.R612* | Nonsense Mutation (SNP) | VAF 21/490 reads (4%) | called by muse, mutect2
- PDZK1 | c.461G>C p.G154A | Missense Mutation (SNP) | VAF 19/357 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.847); called by muse, mutect2
- PMCH | c.138A>C p.K46N | Missense Mutation (SNP) | VAF 43/333 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.197); called by muse, mutect2, varscan2
- PRX | c.598G>T p.E200* | Nonsense Mutation (SNP) | VAF 16/72 reads (22%) | called by muse, mutect2, varscan2
- RPL5 | c.185_187delinsTT p.C62Ffs*8 | Frame Shift Del (DEL) | VAF 40/392 reads (10%) | called by pindel, varscan2*
- SLC45A2 | c.329G>T p.G110V | Missense Mutation (SNP) | VAF 39/279 reads (14%) | SIFT tolerated (0.13); PolyPhen benign (0.151); called by muse, mutect2, varscan2
- TMEM131 | c.5328del p.W1777Gfs*133 | Frame Shift Del (DEL) | VAF 34/223 reads (15%) | called by mutect2, pindel, varscan2
- TRIM58 | c.250C>T p.R84W | Missense Mutation (SNP) | VAF 7/35 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.586); called by muse, mutect2, varscan2
- CFAP47 | c.7173A>T p.L2391= | Silent (SNP) | VAF 44/281 reads (16%) | called by muse, mutect2, varscan2
- HTR6 | c.1149C>T p.D383= | Silent (SNP) | VAF 32/318 reads (10%) | catalogued as rs202070006; called by muse, mutect2, varscan2
- MAGEB6 | c.330A>T p.S110= | Silent (SNP) | VAF 49/516 reads (9%) | called by muse, mutect2, varscan2
- UTRN | c.9561T>C p.H3187= | Silent (SNP) | VAF 31/168 reads (18%) | catalogued as rs1316531299; called by muse, mutect2, varscan2
- ZNF792 | c.663C>G p.A221= | Silent (SNP) | VAF 21/156 reads (13%) | called by muse, mutect2, varscan2
- DCLRE1CP1 | n.142G>A | RNA (SNP) | VAF 52/356 reads (15%) | called by muse, mutect2, varscan2
- FAM182B | n.736G>A | RNA (SNP) | VAF 36/278 reads (13%) | catalogued as rs1371973294; called by muse, varscan2
- PKM | c.1141-616dup | Intron (INS) | VAF 16/108 reads (15%) | catalogued as rs752224534; called by mutect2, varscan2
- STIP1 | c.-30A>G | 5'UTR (SNP) | VAF 39/380 reads (10%) | called by muse, mutect2, varscan2
- VSTM2A | c.634+3809G>A | Intron (SNP) | VAF 46/380 reads (12%) | catalogued as rs1187062713; called by muse, mutect2, varscan2
